CCDI case PBCLFW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/91031f86-29bd-4684-85bf-0d8f6e540357

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.3 years (2,678 days).

Biospecimens (2 samples)
- Sample 0DUHGB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUHHY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
